Gene-level copy-number profile of specimen HCM-WCMC-1294-C18-85A from HCMI case HCM-WCMC-1294-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G3; Age at diagnosis: 47.1 years (17,190 days).
Specimen HCM-WCMC-1294-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 24463ca4-7367-4bf4-ba7f-7dd0253e391e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-WCMC-1294-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/2940504c-925f-4863-9ed0-f021d8d29445

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 52; copy number 2: 13,552; copy number 3: 30,248; copy number 4: 11,079; copy number 5: 360; copy number 6: 3,087; copy number 7: 147; copy number 8: 238; copy number 9: 132; copy number 10: 6; copy number 11: 1; copy number 15: 2.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:105,620,506–105,673,314, 7 genes (within-gene range 0–3): IGHG4, MIR8071-1, IGHG2, MIR8071-2, COPDA1, IGHGP, ELK2AP.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 526 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,425,980–2,526,597, 4 genes, copy number 7: PLCH2, AL139246.1, AL139246.4, PANK4.
- chr7:27,830,573–34,299,012, 110 genes, copy number 8 (within-gene range 4–8) (broad region; genes not listed).
- chr7:56,805,336–56,848,800, 2 genes, copy number 15: CICP28, AC118758.2.
- chr7:149,776,042–149,833,979, 1 gene, copy number 10: SSPOP.
- chr8:115,408,496–115,809,673, 1 gene, copy number 7 (within-gene range 6–7): TRPS1.
- chr8:115,950,511–122,428,551, 65 genes, copy number 7 (broad region; genes not listed).
- chr8:122,485,515–122,489,815, 1 gene, copy number 7: AC108136.1.
- chr8:140,505,813–144,605,816, 176 genes, copy number 7–9 (broad region; genes not listed).
- chr11:1,389,899–1,462,689, 1 gene, copy number 7: BRSK2.
- chr12:132,169,823–132,170,043, 1 gene, copy number 8: AC138466.3.
- chr14:18,333,726–18,419,273, 3 genes, copy number 9–11: CR383658.1, CR383658.2, BNIP3P6.
- chr16:1,148,224–1,221,771, 4 genes, copy number 7 (within-gene range 5–7): AC120498.8, CACNA1H, AC120498.3, AC120498.1.
- chr20:63,540,810–63,556,695, 3 genes, copy number 10: SRMS, AL121829.2, FNDC11.
- chr22:21,919,425–22,273,020, 38 genes, copy number 8: PPM1F, PPM1F-AS1, TOP3B, PRAMENP, IGLVI-70, IGLV4-69, IGLVI-68, AC245452.4, AC245452.3, IGLV10-54, IGLV10-67, AC245452.2, IGLVIV-66-1, IGLVV-66, IGLVIV-65, IGLVIV-64, IGLVI-63, IGLV1-62, AC245517.5, IGLV8-61, AC245517.1, ABHD17AP5, AC245517.4, AC245517.3, IGLV4-60, AC245517.2, SOCS2P2, IGLVIV-59, IGLVV-58, BMP6P1, IGLV6-57, IGLVI-56, IGLV11-55, IGLVIV-53, TOP3BP1, AC245060.3, VPREB1, AC245060.6.
- chr22:22,298,124–23,486,980, 115 genes, copy number 8–10 (broad region; genes not listed).
- chr22:24,719,034–24,774,720, 1 gene, copy number 7: PIWIL3.

Autosomal genes at a single copy (total copy number 1): 52. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
